Surgical pathology report (de-identified scan), TCGA case TCGA-B8-A54F, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-A54F-01A (Primary Tumor).

[page 1 of 3]
Carcinoma, renal cell NOS
Clear Cell type 8312/3

Site: Kidney, NOS
11/30/12 40 C649

Diagnosis:

Kidney, left, radical nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, clear cell type

Sarcomatoid features: not identified

Histologic grade (if applicable): 2 (of 4)

Tumor size (greatest dimension): 3.5 cm

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: not identified

Gerota' s fascia not identified

Renal sinus: not identified

Major veins (renal vein or segmental branches, IVC): not identified

Ureter: not identified

Venous (large vessel): not identified

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Gerota' s fascia (nephrectomy): free of tumor

Renal vein (nephrectomy): free of tumor

Ureter (nephrectomy): free of tumor

Adrenal gland: not present in specimen

Lymph nodes: none present in specimen

Other significant findings: A tiny incidental medullary spindle cell nodule consistent with a microscopic leiomyoma is present (block A6).

AJCC Staging:

pT1a

pNx

[page 2 of 3]
This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

year-old female with a left renal mass.

Gross Description:

Specimen fixation: formalin

Type of specimen: left radical

Side of specimen: left kidney

Size and weight of specimen: 17.2 x 11.0 x 6.5 cm; 435 grams

Orientation: Inking: perirenal fat=green

Presence/absence of adrenal gland: absent

Tumor site: mid portion

Tumor description: circumscribed, cystic, hemorrhagic

Tumor size: 3.5 x 3.0 x 2.9 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: confined

Extent of invasion:

Perirenal adipose tissue: does not involve

Gerota' s fascia: does not involve

Renal vein: does not involve

Ureter: does not involve

[page 3 of 3]
Renal Sinus: does not involve

Pelvicaliceal: does not involve

Adrenal: not present

Other organs: none present

Surgical margins:

Perirenal adipose tissue: negative

Renal vein: negative

Renal artery: negative

Ureter: negative

Description of kidney away from tumor: pink, homogeneous

Hilar lymph nodes: none identified

Other significant findings: There is a small, homogenous, well-circumscribed 0.4 cm white nodule 1.5 cm inferior to the tumor

Tissue submitted for special investigations: none

Digital picture: not taken

Block summary:

- A1 - ureter, vein and artery margins
- A2 - tumor and renal sinus
- A3 - tumor and proximal
- A4 - tumor and capsule
- A5 - normal kidney
- A6 - normal kidney
- A7 - additional section of kidney with small white nodule

ICCA Discrepancy		
Metastatic History		

Source: NCI Genomic Data Commons file de2b3809-f0f0-4e2e-a26a-d0294d20c054 (TCGA-B8-A54F.333EFFED-B7ED-4113-8EE4-B2734B8072F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).